CCDI case PBBKEG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c63a7eed-3832-42f0-91d8-c1dcc774c272

Demographics
Sex at birth: female; Race: asian; Vital status: Dead.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 1.0 years (355 days).

Biospecimens (3 samples)
- Sample 0DB97P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB97T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB97Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
